Somatic mutation profile of tumor specimen TCGA-ER-A2NC-06A (aliquot TCGA-ER-A2NC-06A-11D-A197-08) from TCGA case TCGA-ER-A2NC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 53.5 years (19,556 days).
Specimen TCGA-ER-A2NC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b913527-2907-4006-b096-c460e6054c10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A2NC-10A (Blood Derived Normal), aliquot TCGA-ER-A2NC-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34745fc1-1ae6-4311-a7a3-fd43eeb40e4e

The open-access MAF lists 475 somatic variants for this specimen: 301 protein-altering or splice-affecting, 157 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 276, Silent 157, Nonsense Mutation 18, RNA 7, Intron 6, Splice Region 3, Splice Site 2, 5'UTR 2, 5'Flank 1, Translation Start Site 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL16 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs768772097, COSV61266597; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 47/121 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADAC | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV51760076; called by muse, mutect2, varscan2
- AARS1 | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55748145; called by muse, mutect2, varscan2
- ABCA12 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as COSV55964861; called by muse, mutect2, varscan2
- ABTB2 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV54391014; called by muse, mutect2, varscan2
- ACSF3 | c.1103T>C p.L368P | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58079446; called by muse, mutect2, varscan2
- ADAM18 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55850127; called by muse, mutect2, varscan2
- ADAM23 | c.1318C>T p.Q440* | Nonsense Mutation (SNP) | VAF 68/244 reads (28%) | catalogued as COSV52216622; called by muse, mutect2, varscan2
- ADAMTS9 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 188/659 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55784411; called by muse, mutect2, varscan2
- ALDH8A1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55642662, COSV99664575; called by muse, mutect2, varscan2
- ANKRD11 | c.5813C>T p.P1938L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs535648640, COSV99968574; called by muse, mutect2, varscan2
- ANKRD11 | c.5812C>A p.P1938T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.086); catalogued as COSV56361405, COSV99968575; called by muse, mutect2, varscan2
- APOB | c.9460G>A p.E3154K | Missense Mutation (SNP) | VAF 350/707 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51934657; called by muse, mutect2, varscan2
- APOBEC3F | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV100415131; called by muse, mutect2, varscan2
- APOL3 | c.880G>A p.E294K (on ENST00000349314 / NM_145640.2; = p.E223K on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV62579136; called by muse, mutect2, varscan2
- ARFGEF2 | c.3080G>C p.G1027A | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV64213295; called by muse, mutect2, varscan2
- ARHGEF6 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51687449; called by muse, mutect2
- ARRDC5 | c.86G>A p.R29K (on ENST00000381781; = p.R15K on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV67788091; called by muse, mutect2, varscan2
- AXL | c.1411C>T p.L471F (on ENST00000301178 / NM_021913.5; = p.L462F on NM_001699.6) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV56570402; called by muse, mutect2, varscan2
- B3GAT1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs1229449843, COSV56998602; called by muse, mutect2, varscan2
- BCLAF1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as COSV62140394; called by muse, mutect2, varscan2
- BCLAF1 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs779833402, COSV62140619; called by muse, mutect2, varscan2
- BCR | c.1828C>T p.Q610* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV59933186; called by muse, mutect2, varscan2
- BRD1 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.161); catalogued as rs754769540, COSV53459004; called by muse, mutect2, varscan2
- C14orf39 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.294); catalogued as COSV58783095; called by muse, mutect2, varscan2
- CADPS | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV51876366; called by muse, mutect2, varscan2
- CARD10 | c.2285C>T p.T762I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99324741; called by muse, mutect2, varscan2
- CATSPERB | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56421924; called by muse, mutect2, varscan2
- CATSPERB | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs139686935; called by muse, mutect2, varscan2
- CCNB3 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV52075596; called by muse, mutect2, varscan2
- CCR3 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs371704270; called by muse, mutect2, varscan2
- CCSER1 | c.206G>C p.S69T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV61442782; called by muse, varscan2
- CD163L1 | c.2971C>T p.H991Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV100550304, COSV58018960; called by muse, mutect2, varscan2
- CD1B | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1557821140, COSV63804230; called by muse, mutect2, varscan2
- CDH17 | c.143T>A p.I48K | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV50331624; called by muse, mutect2, varscan2
- CDH7 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59883306; called by muse, mutect2, varscan2
- CEACAM6 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as rs782022161, COSV52266484, COSV52266573, COSV52267133; called by muse, mutect2, varscan2
- CENPF | c.4661C>T p.S1554F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV65276201; called by muse, mutect2, varscan2
- CFAP92 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs757196550, COSV54047483; called by muse, mutect2, varscan2
- CFAP94 | c.143G>A p.R48Q (on ENST00000320267 / NM_001352064.2; = p.R54Q on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs140615558; called by muse, mutect2, varscan2
- CFH | c.3110G>A p.W1037* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as CM1512054, COSV100809066, COSV66408522; called by muse, mutect2, varscan2
- CHL1 | c.3568G>A p.E1190K (on ENST00000397491 / NM_001253387.1; = p.E1206K on NM_006614.4) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV56587977; called by muse, mutect2, varscan2
- CIAPIN1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV67953433; called by muse, mutect2, varscan2
- CLGN | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV57774015; called by muse, mutect2
- CNGB3 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs376711003, COSV60692258; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN2 | c.3083C>T p.S1028F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100084766; called by muse, mutect2, varscan2
- CNTN3 | c.2552C>T p.S851L | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV55176041; called by muse, mutect2, varscan2
- CNTNAP1 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV52851808; called by muse, mutect2, varscan2
- COL21A1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55168981, COSV99780203; called by muse, mutect2, varscan2
- COL22A1 | c.1804G>A p.G602R | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57327671; called by muse, mutect2, varscan2
- COL2A1 | c.4051G>A p.E1351K | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1400106095, COSV61531911; called by muse, mutect2, varscan2
- COL2A1 | c.3896G>A p.W1299* | Nonsense Mutation (SNP) | VAF 30/102 reads (29%) | catalogued as COSV61531915; called by muse, mutect2, varscan2
- COL4A5 | c.2597G>T p.G866V | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960377, COSV60364809; called by muse, mutect2, varscan2
- CPO | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.275); catalogued as rs866274262, COSV55940272; called by muse, mutect2, varscan2
- CRB2 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63504056; called by muse, mutect2, varscan2
- CSMD1 | c.9816A>G p.I3272M (on ENST00000520002; = p.I3271M on NM_033225.6) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs1279271087, COSV59342914; called by muse, varscan2
- CSMD1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.8); PolyPhen benign (0.039); catalogued as rs369063062, COSV68263821; called by muse, mutect2, varscan2
- CX3CR1 | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as COSV64194318; called by muse, mutect2, varscan2
- CYLC1 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV61411337; called by muse, mutect2, varscan2
- CYP2J2 | c.1116G>A p.M372I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs764608206, COSV64606182; called by muse, mutect2, varscan2
- CYP3A43 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs201674434; called by muse, mutect2, varscan2
- CYP4Z1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV61965435; called by muse, mutect2, varscan2
- DAGLA | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565262820, COSV57197477, COSV99944572; called by muse, mutect2, varscan2
- DCAF8L1 | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV71595369; called by muse, mutect2
- DCC | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.464); catalogued as COSV59113201; called by muse, mutect2, varscan2
- DDR1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61321311; called by muse, mutect2, varscan2
- DENND2A | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV52053729; called by muse, mutect2, varscan2
- DENND4C | c.3671C>T p.S1224F (on ENST00000434457 / NM_001330640.2; = p.S1175F on NM_017925.7) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV63009163; called by muse, mutect2, varscan2
- DEPDC4 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV54553890, COSV54554397; called by muse, mutect2, varscan2
- DMBT1 | c.7558G>A p.E2520K (on ENST00000338354 / NM_001377530.1; = p.E1763K on NM_004406.3) | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV57534694; called by muse, mutect2, varscan2
- DNAH2 | c.3780G>A p.M1260I | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV66721662; called by muse, mutect2, varscan2
- DNAH7 | c.3890A>T p.N1297I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV56771881; called by muse, mutect2, varscan2
- DST | c.2446G>A p.E816K (on ENST00000361203 / NM_001374722.1; = p.E490K on NM_001723.6) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV55023521; called by muse, mutect2, varscan2
- DYSF | c.4966G>A p.D1656N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50460162; called by muse, mutect2, varscan2
- EBNA1BP2 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV52540389, COSV99355859; called by muse, mutect2, varscan2
- EBNA1BP2 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.136); catalogued as rs201723368, COSV99355863; called by muse, mutect2, varscan2
- ELFN2 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101297570, COSV68745145; called by muse, mutect2, varscan2
- ENPP4 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.095); catalogued as COSV58089343; called by muse, mutect2, varscan2
- EPN1 | c.904C>T p.P302S (on ENST00000270460 / NM_001321263.1; = p.P277S on NM_013333.3) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs552668371, COSV50039534; called by muse, mutect2, varscan2
- EVPL | c.4405G>A p.E1469K | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV56912820; called by muse, mutect2, varscan2
- F2RL3 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1358140437, COSV50185828; called by muse, mutect2, varscan2
- FAM151A | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as COSV56364789; called by muse, mutect2, varscan2
- FAM184A | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.566); catalogued as COSV58854308; called by muse, mutect2, varscan2
- FAP | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1330326419, COSV51863850, COSV99502789; called by muse, mutect2, varscan2
- FASTKD5 | c.1067T>C p.L356S | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53907009; called by muse, mutect2, varscan2
- FGFR2 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60651312, COSV60655961; called by muse, mutect2, varscan2
- FGL2 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1373659990, COSV50380405; called by muse, mutect2, varscan2
- FHL5 | c.160-1G>A p.X54_splice | Splice Site (SNP) | VAF 36/74 reads (49%) | catalogued as COSV100459800, COSV100459851, COSV58738588; called by muse, mutect2, varscan2
- FLVCR1 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs144013956, COSV65323693; called by muse, mutect2
- FRAS1 | c.3364G>A p.D1122N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.764); catalogued as COSV53623160; called by muse, mutect2, varscan2
- FZD9 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1257627061, COSV59992204; called by muse, mutect2, varscan2
- G6PC2 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV56372511; called by muse, mutect2, varscan2
- GALNT8 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52898837; called by muse, mutect2, varscan2
- GBP2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV65069787; called by muse, mutect2, varscan2
- GDF3 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867390778, COSV61712125; called by muse, mutect2, varscan2
- GIMAP4 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99750516; called by muse, mutect2, varscan2
- GPR179 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753604281; called by muse, mutect2, varscan2
- GPR61 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as COSV63984032; called by muse, mutect2, varscan2
- GRM6 | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs62638211, COSV99179488; ClinVar: not provided; called by muse, varscan2
- HARBI1 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56321340; called by muse, mutect2, varscan2
- HCN2 | c.2009T>G p.L670R | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52116036; called by muse, mutect2, varscan2
- HEPHL1 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV59893480; called by mutect2, varscan2
- HHLA2 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV63318197; called by muse, mutect2, varscan2
- HSD3B7 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.474); catalogued as COSV52680937; called by muse, mutect2, varscan2
- HYDIN | c.12356C>T p.S4119F | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); catalogued as COSV66636817; called by muse, mutect2, varscan2
- HYDIN | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.12); catalogued as rs1207757687, COSV55479303; called by muse, mutect2, varscan2
- IGHV3-16 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.964); catalogued as rs782023969; called by muse, mutect2, varscan2
- IGHV3-53 | c.314G>C p.R105T | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.411); catalogued as rs782464399; called by muse, mutect2
- IQCE | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV58079549; called by muse, mutect2
- ITIH3 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs757307789, COSV69648023; called by muse, mutect2, varscan2
- JAKMIP3 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 110/158 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as rs748242503, COSV53825176; called by muse, mutect2, varscan2
- JPH1 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 12/18 reads (67%) | catalogued as COSV60612256, COSV60612598; called by muse, mutect2, varscan2
- KCNH7 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as rs758119259, COSV59801779, COSV59804711; called by muse, mutect2, varscan2
- KCNK10 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV56640972; called by muse, mutect2, varscan2
- KDM5B | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866376976, COSV52509447; called by muse, mutect2, varscan2
- KIAA1549 | c.5174C>T p.S1725F | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV54318437; called by muse, mutect2, varscan2
- KIF2C | c.1511G>A p.S504N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as rs777605365, COSV64764931; called by muse, mutect2, varscan2
- KLHL40 | c.1675C>T p.L559F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55135419; called by muse, mutect2, varscan2
- KLK10 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.921); catalogued as COSV59398648; called by muse, mutect2, varscan2
- KMT2A | c.5770G>A p.A1924T | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100628232; called by muse, mutect2, varscan2
- KRT6B | c.995G>A p.S332N | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV52882227, COSV52884561, COSV52885054; called by muse, mutect2, varscan2
- KSR1 | c.1406C>T p.S469F (on ENST00000644974 / NM_001367810.1; = p.S332F on NM_014238.2) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV52034889; called by muse, mutect2, varscan2
- LAPTM4B | c.685C>T p.P229S (on ENST00000445593; = p.P138S on NM_018407.6) | Missense Mutation (SNP) | VAF 82/106 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV71454386; called by muse, mutect2, varscan2
- LGALS4 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV99669481; called by muse, mutect2, varscan2
- LIFR | c.2504G>A p.G835E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54689904, COSV54693163; called by muse, mutect2, varscan2
- LMNTD2 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs765987111, COSV99529684; called by muse, mutect2, varscan2
- LMOD3 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV70456289; called by muse, mutect2, varscan2
- LRRN1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267599792, COSV60013540; called by muse, mutect2, varscan2
- LUZP2 | c.975A>T p.K325N | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as rs777080312, COSV61209636; called by muse, mutect2, varscan2
- MARVELD2 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs141046438, COSV57781253; called by muse, mutect2, varscan2
- MECOM | c.899C>T p.S300F (on ENST00000468789 / NM_001105078.4; = p.S488F on NM_004991.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.556); catalogued as rs267599685, COSV52961844; called by muse, mutect2, varscan2
- MEIS1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV55488683; called by muse, mutect2, varscan2
- MIA2 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs754149612, COSV54482945; called by muse, mutect2, varscan2
- MITF | c.185T>A p.L62H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58885573; called by muse, mutect2, varscan2
- MLPH | c.1236G>T p.K412N | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.106); catalogued as COSV52821728, COSV52822446; called by muse, mutect2, varscan2
- MPP7 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0.179); catalogued as rs147738330; called by muse, mutect2, varscan2
- MPPED2 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63899421; called by muse, mutect2, varscan2
- MUC16 | c.27250G>A p.G9084S | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.318); catalogued as rs756945009, COSV67476169; called by muse, mutect2, varscan2
- MUC16 | c.15346G>A p.E5116K | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.041); catalogued as rs866107833, COSV67449897; called by muse, mutect2, varscan2
- MUC17 | c.4777C>T p.L1593F | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.262); catalogued as COSV60293528; called by muse, mutect2, varscan2
- MYBPHL | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 122/384 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64062707; called by muse, mutect2, varscan2
- MYH3 | c.4088C>T p.S1363F | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56866772; called by muse, mutect2, varscan2
- MYH4 | c.2937G>A p.V979= | Splice Region (SNP) | VAF 48/144 reads (33%) | catalogued as COSV55113933; called by muse, mutect2, varscan2
- MYH9 | c.4535C>T p.S1512F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53381855; called by muse, mutect2, varscan2
- MYH9 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs1247656863, COSV99338129; called by muse, mutect2, varscan2
- MYO1B | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as COSV58433399; called by muse, mutect2, varscan2
- MYO1C | c.2894C>T p.T965I (on ENST00000648651 / NM_001080779.2; = p.T930I on NM_033375.5) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.296); catalogued as COSV62999756; called by muse, mutect2, varscan2
- MYO5B | c.2875G>A p.V959I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs1404964121, COSV53212608; called by muse, mutect2, varscan2
- MYOCD | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV58506469, COSV58513507; called by muse, mutect2, varscan2
- MYOCD | c.1125+1G>A p.X375_splice | Splice Site (SNP) | VAF 23/75 reads (31%) | catalogued as COSV58506485; called by muse, mutect2, varscan2
- NCOR2 | c.4298T>C p.L1433P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1326939043, COSV62300003; called by muse, varscan2
- NETO1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs267605254, COSV55001194; called by muse, mutect2, varscan2
- NHP2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1437749662, COSV51071078; called by muse, mutect2, varscan2
- NLRC3 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV57092678; called by muse, mutect2, varscan2
- NLRP4 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs373819293; called by muse, mutect2, varscan2
- NLRP5 | c.2201G>C p.R734P | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV101173528, COSV66762506, COSV66765656; called by muse, mutect2, varscan2
- NUTM1 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV61546825; called by muse, mutect2, varscan2
- OAS3 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV57446976; called by muse, mutect2, varscan2
- OPRPN | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.019); catalogued as COSV68193152; called by muse, mutect2, varscan2
- OR10G8 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101461805; called by muse, varscan2
- OR11H12 | c.569A>T p.D190V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1163449514, COSV101612465; called by mutect2, varscan2
- OR2C3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs200581250, COSV63574834; called by muse, mutect2, varscan2
- OR2J3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 70/140 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); catalogued as COSV65849267; called by muse, mutect2, varscan2
- OR2T3 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100613333, COSV62082804; called by mutect2, varscan2
- OR2T34 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100170477, COSV60900930; called by mutect2, varscan2
- OR2T34 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.416); catalogued as COSV60900938; called by muse, mutect2, varscan2
- OR4E2 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs755573369, COSV57731770; called by muse, mutect2, varscan2
- OR4K1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 87/425 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV53460913; called by muse, mutect2, varscan2
- OR5D14 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV59455419; called by muse, mutect2, varscan2
- OSBPL7 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99136577; called by muse, mutect2, varscan2
- OVOL2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1419305548, COSV53859667, COSV53861786; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1280T>C p.L427S (on ENST00000259318 / NM_001136562.3; = p.L658S on NM_007203.5) | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.077); catalogued as COSV52178342; called by muse, mutect2, varscan2
- PAPPA2 | c.4327G>A p.E1443K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100868379, COSV62798918; called by muse, mutect2, varscan2
- PARM1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV56655549; called by muse, mutect2, varscan2
- PARP9 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV64451084; called by muse, mutect2, varscan2
- PC | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 75/130 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63081437; called by muse, mutect2, varscan2
- PCDH15 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.73); PolyPhen benign (0.028); catalogued as COSV57279874; called by muse, mutect2, varscan2
- PCDHA11 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56518578; called by muse, mutect2, varscan2
- PCDHA3 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs148196865, COSV63538858; called by muse, mutect2, varscan2
- PCDHB4 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV52022541; called by muse, mutect2, varscan2
- PCLAF | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs1056607258, COSV55540022, COSV55540419; called by muse, mutect2, varscan2
- PCLO | c.12404G>A p.G4135E | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61645399; called by muse, mutect2, varscan2
- PDE10A | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as COSV63099949; called by muse, mutect2, varscan2
- PGBD1 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV52554268; called by muse, mutect2, varscan2
- PHRF1 | c.1988C>T p.P663L (on ENST00000264555 / NM_001286581.2; = p.P662L on NM_020901.4) | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs761966213, COSV52757905; called by muse, mutect2, varscan2
- PKHD1L1 | c.3487G>A p.D1163N | Missense Mutation (SNP) | VAF 247/315 reads (78%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs1229740011, COSV65746325; called by muse, mutect2, varscan2
- PLA2G4A | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66554951; called by muse, mutect2, varscan2
- PLCH1 | c.1396G>A p.D466N (on ENST00000340059 / NM_001130960.2; = p.D478N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58202233; called by muse, mutect2, varscan2
- PLEKHG3 | c.3056C>T p.P1019L (on ENST00000394691; = p.P1075L on NM_001308147.2) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs888543959, COSV55981161; called by muse, mutect2, varscan2
- PLXNA1 | c.2159G>T p.G720V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52528570; called by muse, mutect2, varscan2
- PLXNA4 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as rs762255363, COSV58109128; called by muse, mutect2, varscan2
- PRAMEF15 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 188/489 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.02); catalogued as rs1229360594; called by muse, mutect2, varscan2
- PRPF4B | c.2633C>T p.T878I | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61784580; called by muse, mutect2, varscan2
- PRRC2A | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV63224767; called by muse, mutect2, varscan2
- PSTK | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1194841358, COSV64398725; called by muse, mutect2, varscan2
- PTGER3 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV60688373, COSV60692222; called by muse, mutect2, varscan2
- PTPRB | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV54245082; called by muse, mutect2, varscan2
- PWWP3B | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV61798632; called by muse, mutect2, varscan2
- QRSL1 | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as COSV64687853; called by muse, mutect2, varscan2
- RAB11FIP4 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57930431; called by muse, mutect2
- RAI1 | c.3931C>T p.Q1311* | Nonsense Mutation (SNP) | VAF 60/131 reads (46%) | catalogued as COSV99883575; called by muse, mutect2, varscan2
- RBM12B | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 136/187 reads (73%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1445416369, COSV67898331; called by muse, mutect2, varscan2
- REG3A | c.399G>A p.W133* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as rs1442404983, COSV59410260; called by muse, mutect2, varscan2
- RMDN3 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV99539888; called by muse, mutect2, varscan2
- RPL3 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as COSV53365797; called by muse, mutect2, varscan2
- RPTN | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 173/465 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1373863773, COSV60167425; called by muse, mutect2, varscan2
- RTP1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV56618853; called by muse, mutect2, varscan2
- RYR3 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66797254; called by muse, mutect2, varscan2
- SAA1 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.574); catalogued as COSV62946395; called by muse, mutect2, varscan2
- SAMD15 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770683865, COSV53626865; called by muse, mutect2, varscan2
- SAMHD1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1241476824, COSV53430674; called by muse, mutect2, varscan2
- SCN10A | c.3199G>A p.D1067N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV71860532, COSV71861954; called by muse, mutect2, varscan2
- SCN10A | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71861955; called by muse, mutect2, varscan2
- SCN11A | c.4624C>T p.L1542F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56572936; called by muse, mutect2, varscan2
- SCN2A | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV51846388; called by muse, mutect2, varscan2
- SCN3A | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV51814758; called by muse, mutect2, varscan2
- SCN4A | c.3485A>G p.N1162S | Missense Mutation (SNP) | VAF 92/290 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV71127517; called by muse, mutect2, varscan2
- SCN9A | c.5432C>T p.P1811L (on ENST00000303354; = p.P1800L on NM_002977.3) | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV57614551; called by muse, mutect2, varscan2
- SDK2 | c.2371C>T p.P791S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV66181753; called by muse, mutect2
- SGIP1 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs139418191; called by muse, mutect2, varscan2
- SHROOM4 | c.3772C>T p.Q1258* | Nonsense Mutation (SNP) | VAF 22/29 reads (76%) | catalogued as COSV56791950; called by muse, mutect2, varscan2
- SI | c.3760G>A p.D1254N | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52285998; called by muse, mutect2, varscan2
- SI | c.2380G>A p.G794S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138778317; called by muse, mutect2, varscan2
- SIGLEC8 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.118); catalogued as COSV58474460; called by muse, mutect2, varscan2
- SLC30A10 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs1370133815, COSV63072652, COSV99055445; called by muse, mutect2, varscan2
- SLC6A3 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV54365873; called by muse, mutect2, varscan2
- SLC9A2 | c.1820G>A p.R607K | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV52131153, COSV52133766; called by muse, mutect2, varscan2
- SLIT2 | c.3344C>T p.P1115L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV56578956; called by muse, mutect2, varscan2
- SPAG17 | c.4165C>T p.H1389Y | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV60461910; called by muse, mutect2, varscan2
- SPATA31E1 | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as rs1422383825, COSV100350068; called by muse, mutect2, varscan2
- SPDYA | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as rs1271263522, COSV100477872; called by muse, mutect2, varscan2
- SPTB | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs867858924, COSV67632972; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPZ1 | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV57063910; called by muse, mutect2, varscan2
- SSR1 | c.792C>T p.I264= | Splice Region (SNP) | VAF 17/38 reads (45%) | catalogued as rs778131647, COSV55203593; called by muse, mutect2, varscan2
- STARD13 | c.3299C>T p.S1100F (on ENST00000336934 / NM_001243476.3; = p.S982F on NM_052851.3) | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV55229170, COSV55232831; called by muse, mutect2, varscan2
- STK17A | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.414); catalogued as COSV60047778; called by muse, mutect2, varscan2
- STK24 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 121/218 reads (56%) | catalogued as COSV64823213; called by muse, mutect2, varscan2
- STON1 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs144911860, COSV59132866; called by muse, mutect2, varscan2
- SUCO | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV55267289; called by muse, mutect2, varscan2
- SYCP2L | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV51654738; called by muse, mutect2, varscan2
- TBX15 | c.1417C>T p.P473S (on ENST00000369429 / NM_001330677.2; = p.P367S on NM_152380.3) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs1557868291, COSV52876715; called by muse, varscan2
- TFPI | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865913136, COSV51898677; called by muse, mutect2, varscan2
- TGM1 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as rs1033892140, COSV52863633; called by muse, mutect2, varscan2
- THRB | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54980941; called by muse, mutect2, varscan2
- THSD7B | c.3595G>A p.E1199K (on ENST00000272643; = p.E1197K on NM_001316349.2) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763724242, COSV55705268; called by muse, mutect2, varscan2
- TMED8 | c.811G>T p.G271C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV53626861; called by muse, mutect2, varscan2
- TMEM11 | c.172A>C p.K58Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100471706; called by muse, mutect2, varscan2
- TMEM11 | c.171C>A p.Y57* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100471709; called by muse, mutect2, varscan2
- TMEM131 | c.4955G>A p.G1652D | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as COSV51781392; called by muse, mutect2, varscan2
- TMEM131 | c.4954G>A p.G1652S | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as COSV51778802, COSV99486903; called by muse, mutect2, varscan2
- TMEM132B | c.2562G>A p.M854I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs866126954, COSV54758402; called by muse, mutect2, varscan2
- TMEM167B | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 141/421 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.778); catalogued as COSV57808334; called by muse, mutect2, varscan2
- TMEM241 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67244501; called by muse, mutect2, varscan2
- TMEM255B | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1207929065, COSV64704252; called by muse, mutect2, varscan2
- TMIGD2 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.258); catalogued as COSV56667582; called by muse, mutect2, varscan2
- TPD52L2 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs150777439; called by muse, mutect2, varscan2
- TRAV20 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs757418657; called by muse, mutect2, varscan2
- TRIML2 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as COSV100456202, COSV58717537; called by muse, mutect2, varscan2
- TRIOBP | c.4732C>T p.P1578S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.942); catalogued as COSV60374839; called by muse, mutect2, varscan2
- TRMT1 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1568377401, COSV52835024; called by muse, mutect2, varscan2
- TRPC4AP | c.1514G>T p.S505I | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV52681479; called by muse, mutect2, varscan2
- TRPM4 | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV53264924; called by muse, mutect2, varscan2
- TRPV5 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV54687288; called by muse, mutect2, varscan2
- TSPOAP1 | c.3847C>T p.Q1283* | Nonsense Mutation (SNP) | VAF 45/83 reads (54%) | catalogued as COSV52111759; called by muse, mutect2, varscan2
- TTC16 | c.1626G>A p.W542* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV60161441; called by muse, mutect2, varscan2
- TTLL9 | c.566G>A p.W189* | Nonsense Mutation (SNP) | VAF 53/99 reads (54%) | catalogued as COSV60593807; called by muse, mutect2, varscan2
- TTN | c.8773G>A p.E2925K (on ENST00000591111; = p.E2879K on NM_003319.4) | Missense Mutation (SNP) | VAF 85/257 reads (33%) | PolyPhen benign (0.359); catalogued as rs988120503, COSV60158916; called by muse, mutect2, varscan2
- UBA2 | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 7/101 reads (7%) | catalogued as COSV55825733, COSV99874892; called by muse, mutect2
- UGT2A3 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV52360848; called by muse, mutect2, varscan2
- UGT3A1 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV57099628; called by muse, mutect2, varscan2
- UNC13A | c.3406G>A p.D1136N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV53196907, COSV99407446; called by muse, mutect2, varscan2
- UNC93A | c.843C>T p.S281= | Splice Region (SNP) | VAF 106/423 reads (25%) | catalogued as COSV57809231; called by muse, mutect2, varscan2
- UPK1A | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs1370278846, COSV55878457; called by muse, varscan2
- USH2A | c.7378C>T p.R2460C | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs866943133, COSV56322035; called by muse, mutect2, varscan2
- USP26 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as rs867690085, COSV63709041; called by muse, mutect2, varscan2
- VAX2 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV52266403; called by muse, mutect2, varscan2
- VPS39 | c.1592C>T p.S531F (on ENST00000348544 / NM_001301138.2; = p.S520F on NM_015289.5) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58790707; called by muse, mutect2, varscan2
- VSX1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 72/133 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868015372, COSV65021697; called by muse, mutect2, varscan2
- WDR49 | c.887C>T p.T296I (on ENST00000308378 / NM_001366158.1; = p.T637I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as COSV57711327; called by muse, mutect2, varscan2
- XRCC5 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); catalogued as COSV67536814; called by muse, mutect2, varscan2
- XRN2 | c.2793T>G p.Y931* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV65870325; called by muse, mutect2
- YEATS2 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV59367844; called by muse, mutect2, varscan2
- YIPF1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs1322586407, COSV50777916; called by muse, mutect2, varscan2
- ZAN | c.5383C>T p.Q1795* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as rs369194516; called by muse, mutect2, varscan2
- ZFP30 | c.309G>A p.W103* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV63622768; called by muse, mutect2, varscan2
- ZFP82 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.78); catalogued as COSV67565737; called by muse, mutect2, varscan2
- ZFYVE16 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100566264; called by mutect2, varscan2
- ZFYVE16 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1460491208, COSV100566265; called by muse, mutect2, varscan2
- ZNF141 | c.1071T>A p.H357Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53659390; called by muse, mutect2
- ZNF141 | c.1073A>G p.K358R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.083); catalogued as COSV53659398; called by muse, mutect2
- ZNF185 | c.1486G>A p.G496S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.51); PolyPhen benign (0.056); catalogued as rs1556908543, COSV100248212, COSV59276735; called by muse, mutect2, varscan2
- ZNF280D | c.2192C>T p.P731L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV50998155; called by muse, mutect2, varscan2
- ZNF324 | c.1241A>G p.K414R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as COSV52181272; called by muse, mutect2, varscan2
- ZNF385B | c.1364C>T p.S455L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs1185975263, COSV61179021; called by muse, mutect2, varscan2
- ZNF518B | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV58723314; called by muse, mutect2, varscan2
- ZNF660 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.831); catalogued as COSV59549464; called by muse, mutect2, varscan2
- ZNF677 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV61720233, COSV61720649; called by muse, mutect2, varscan2
- EPS8 | c.1567del p.R523Efs*21 | Frame Shift Del (DEL) | VAF 19/97 reads (20%) | called by mutect2, pindel, varscan2
- ABCA8 | c.2241C>T p.F747= | Silent (SNP) | VAF 42/148 reads (28%) | catalogued as COSV52204940; called by muse, mutect2, varscan2
- ACSM2A | c.1668G>A p.G556= (on ENST00000219054; = p.G477= on NM_001308169.2) | Silent (SNP) | VAF 58/183 reads (32%) | catalogued as COSV54586355; called by muse, mutect2, varscan2
- ADGRB3 | c.3795T>G p.L1265= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV53250659; called by muse, mutect2, varscan2
- AL441992.2 | c.708C>T p.S236= | Silent (SNP) | VAF 117/256 reads (46%) | catalogued as COSV56914963; called by muse, mutect2, varscan2
- APLP1 | c.1569C>T p.T523= (on ENST00000221891 / NM_001024807.3; = p.T522= on NM_005166.4) | Silent (SNP) | VAF 80/220 reads (36%) | catalogued as COSV55704693; called by muse, mutect2, varscan2
- ARMC9 | c.1419C>T p.D473= | Silent (SNP) | VAF 42/129 reads (33%) | catalogued as COSV63022000; called by muse, mutect2, varscan2
- ASTN1 | c.3588C>T p.N1196= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as COSV62499598; called by muse, mutect2, varscan2
- ATP2A3 | c.1566C>T p.I522= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs777386907, COSV59230979; called by muse, mutect2, varscan2
- ATRAID | c.774C>T p.F258= (on ENST00000611786; = p.F145= on NM_016085.5) | Silent (SNP) | VAF 66/133 reads (50%) | catalogued as COSV53028614; called by muse, mutect2, varscan2
- C1orf141 | c.333A>G p.E111= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV63992888; called by muse, mutect2, varscan2
- C2CD2 | c.576C>T p.I192= | Silent (SNP) | VAF 56/82 reads (68%) | catalogued as COSV61599887; called by muse, mutect2, varscan2
- CARD10 | c.2286C>T p.T762= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs370782313; called by muse, mutect2, varscan2
- CCSER1 | c.141C>T p.S47= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV61442771; called by muse, varscan2
- CD53 | c.616C>T p.L206= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV54762005; called by muse, mutect2, varscan2
- CERCAM | c.1746C>T p.S582= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV65711322; called by muse, mutect2, varscan2
- CHD3 | c.3340C>T p.L1114= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV57876981; called by muse, mutect2, varscan2
- CHGA | c.228G>A p.L76= | Silent (SNP) | VAF 84/243 reads (35%) | catalogued as rs1399973994, COSV53663673; called by muse, mutect2, varscan2
- CHIT1 | c.960G>A p.Q320= | Silent (SNP) | VAF 55/145 reads (38%) | catalogued as rs374075401; called by muse, mutect2, varscan2
- CHP2 | c.306C>T p.D102= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV55650232; called by muse, mutect2, varscan2
- CHST6 | c.165C>T p.F55= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as CM091074, COSV59999503; called by muse, mutect2, varscan2
- CLC | c.324C>T p.S108= | Silent (SNP) | VAF 72/196 reads (37%) | catalogued as COSV55685816; called by muse, mutect2, varscan2
- CLSTN3 | c.2481G>A p.P827= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs376830897; called by muse, mutect2, varscan2
- CSMD2 | c.10179G>A p.L3393= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV53927128; called by muse, mutect2, varscan2
- CTNND2 | c.2268C>T p.I756= | Silent (SNP) | VAF 71/202 reads (35%) | catalogued as rs767036575, COSV58864248, COSV58899357; called by muse, mutect2, varscan2
- CTR9 | c.1539C>T p.F513= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV63728946; called by muse, mutect2, varscan2
- CYP2S1 | c.927C>T p.T309= | Silent (SNP) | VAF 48/145 reads (33%) | catalogued as COSV59506513; called by muse, mutect2, varscan2
- DBF4B | c.1845T>C p.G615= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV59261610; called by muse, mutect2, varscan2
- DCAF8L1 | c.303G>A p.E101= | Silent (SNP) | VAF 34/50 reads (68%) | catalogued as COSV71595370; called by muse, mutect2
- DCLK3 | c.1125C>T p.H375= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs1429445119, COSV69363777; called by muse, mutect2, varscan2
- DIRAS2 | c.534C>T p.I178= | Silent (SNP) | VAF 40/79 reads (51%) | catalogued as rs904283931, COSV65369952; called by muse, mutect2, varscan2
- DNAH3 | c.6801G>A p.S2267= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV54513106; called by muse, mutect2, varscan2
- DNM1 | c.1116C>T p.F372= | Silent (SNP) | VAF 62/137 reads (45%) | catalogued as rs367584321; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOK3 | c.951C>T p.P317= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV57253056; called by muse, mutect2, varscan2
- DPYD | c.348A>C p.I116= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV60080189; called by muse, mutect2, varscan2
- DRICH1 | c.219G>A p.E73= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV58504169; called by muse, mutect2, varscan2
- DSE | c.2166C>T p.D722= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV100528398; called by muse, mutect2, varscan2
- ECEL1 | c.1173C>T p.S391= | Silent (SNP) | VAF 86/195 reads (44%) | catalogued as COSV58813058; called by muse, mutect2, varscan2
- EDIL3 | c.894C>T p.P298= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV56905484; called by muse, mutect2, varscan2
- ENPEP | c.483C>T p.F161= | Silent (SNP) | VAF 56/203 reads (28%) | catalogued as rs146450390, COSV54446469, COSV54448498; called by muse, mutect2, varscan2
- ENTHD1 | c.120C>T p.I40= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV57321930; called by muse, varscan2
- ENTPD2 | c.369G>A p.A123= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs551022562, COSV57075798; called by muse, mutect2, varscan2
- EPHA10 | c.1569C>T p.T523= | Silent (SNP) | VAF 56/158 reads (35%) | catalogued as rs1233535501, COSV57623942; called by muse, mutect2, varscan2
- EPHA3 | c.2241C>T p.L747= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs1370663734, COSV60702326, COSV60707950; called by muse, mutect2, varscan2
- ERGIC3 | c.642C>T p.F214= | Silent (SNP) | VAF 108/172 reads (63%) | catalogued as COSV54138864; called by muse, mutect2, varscan2
- FAM135A | c.3036C>T p.I1012= (on ENST00000370479 / NM_001351599.1; = p.I799= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV52054034; called by muse, mutect2, varscan2
- FGF5 | c.646C>T p.L216= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV56890745; called by muse, mutect2, varscan2
- FSHR | c.1833G>A p.L611= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs777491270, COSV58627142; called by muse, mutect2, varscan2
- GDPD4 | c.1419C>T p.L473= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs267603201, COSV60020423; called by muse, mutect2, varscan2
- GFOD2 | c.312C>T p.F104= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV52058603; called by muse, mutect2, varscan2
- GPR142 | c.1074C>T p.I358= | Silent (SNP) | VAF 45/71 reads (63%) | catalogued as COSV59518668; called by muse, mutect2, varscan2
- GPR68 | c.333C>T p.F111= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV53176791; called by muse, mutect2, varscan2
- GPX5 | c.558C>T p.F186= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as COSV69079594; called by muse, mutect2, varscan2
- HARBI1 | c.813C>T p.F271= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV58706397; called by muse, mutect2, varscan2
- HARBI1 | c.252C>T p.S84= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as rs1233560479, COSV100365545; called by muse, mutect2, varscan2
- HCN2 | c.681C>T p.I227= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV52116016; called by muse, mutect2, varscan2
- HDC | c.858C>T p.F286= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV51073096; called by muse, mutect2, varscan2
- HIPK1 | c.3234C>T p.S1078= (on ENST00000369558 / NM_001369806.1; = p.S684= on NM_181358.2) | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as rs753009603, COSV61248855; called by muse, mutect2, varscan2
- HIPK3 | c.3531C>T p.T1177= | Silent (SNP) | VAF 70/127 reads (55%) | catalogued as rs768782322, COSV57563559; called by muse, mutect2, varscan2
- IGSF1 | c.2535G>A p.G845= | Silent (SNP) | VAF 133/180 reads (74%) | catalogued as rs757311761, COSV63836363; called by muse, mutect2, varscan2
- INTS7 | c.27C>T p.F9= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV65342708; called by muse, mutect2, varscan2
- IP6K3 | c.1095C>T p.I365= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as COSV99539661; called by muse, mutect2, varscan2
- ITIH3 | c.1308G>A p.L436= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV69649378; called by muse, mutect2
- KCNB1 | c.660C>T p.F220= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs751017425, COSV65566922, COSV65568775; called by muse, mutect2, varscan2
- KEL | c.2049G>A p.R683= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV62333602; called by muse, mutect2, varscan2
- KRT13 | c.373C>T p.L125= | Silent (SNP) | VAF 57/120 reads (48%) | catalogued as COSV55840375, COSV55840430; called by muse, mutect2, varscan2
- LCE1C | c.162C>T p.S54= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV64218722; called by muse, mutect2, varscan2
- LCE3D | c.30C>T p.C10= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV64230877; called by muse, mutect2, varscan2
- LGALS4 | c.66C>T p.P22= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99669479; called by muse, mutect2, varscan2
- LGALS8 | c.312G>A p.E104= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs766994726, COSV53025451; called by muse, mutect2, varscan2
- LILRA2 | c.540C>T p.F180= | Silent (SNP) | VAF 43/194 reads (22%) | catalogued as COSV52193300; called by muse, mutect2, varscan2
- LMX1A | c.477C>T p.S159= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV54223363; called by muse, mutect2, varscan2
- LRRC32 | c.828C>T p.L276= | Silent (SNP) | VAF 42/66 reads (64%) | catalogued as COSV52633787; called by muse, mutect2, varscan2
- LYPD6B | c.354C>T p.V118= (on ENST00000409029 / NM_001317004.1; = p.V142= on NM_177964.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/163 reads (48%) | catalogued as rs961699829, COSV54519449; called by muse, mutect2, varscan2
- MAGEB3 | c.423C>T p.V141= | Silent (SNP) | VAF 22/29 reads (76%) | catalogued as COSV100854711, COSV64397349; called by muse, mutect2, varscan2
- MAP3K10 | c.1806C>T p.I602= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs759300640, COSV53423196; called by muse, mutect2, varscan2
- MB | c.189G>A p.K63= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV63094180; called by muse, mutect2, varscan2
- METTL16 | c.1110C>T p.F370= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as COSV54014555, COSV54017445; called by muse, mutect2, varscan2
- MICALL1 | c.1077C>T p.S359= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs145525171, COSV53241521; called by muse, mutect2, varscan2
- MPP3 | c.567C>T p.I189= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs775273111, COSV68198604; called by muse, mutect2, varscan2
- MYH9 | c.4536C>T p.S1512= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs546744981, COSV99338125, COSV99339152; called by muse, mutect2, varscan2
- NBEAL2 | c.930C>T p.A310= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs775780761, COSV52760009; called by muse, mutect2
- NCKAP1L | c.2688C>T p.P896= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV53208716; called by muse, mutect2, varscan2
- NLRP4 | c.558C>T p.F186= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as COSV56716870; called by muse, mutect2, varscan2
- NLRP4 | c.1092C>T p.T364= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV56716898; called by muse, mutect2, varscan2
- NUTM1 | c.621C>T p.S207= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100412147; called by muse, mutect2, varscan2
- OAS2 | c.354C>T p.F118= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs755316801, COSV60803205; called by muse, mutect2, varscan2
- OBSCN | c.11454G>A p.T3818= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as rs780352614, COSV52765516; called by muse, mutect2, varscan2
- OR10G8 | c.669C>T p.S223= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as rs1483905687, COSV70908120; called by muse, varscan2
- OR2M2 | c.84C>T p.F28= | Silent (SNP) | VAF 85/237 reads (36%) | catalogued as COSV62898700, COSV62899523; called by muse, mutect2, varscan2
- OR4D6 | c.690G>A p.G230= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as COSV55660132; called by muse, mutect2, varscan2
- OR4D9 | c.477G>A p.Q159= | Silent (SNP) | VAF 48/86 reads (56%) | catalogued as COSV61434959; called by muse, mutect2, varscan2
- OR4K14 | c.735C>T p.I245= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1566525460, COSV59291988; called by mutect2, varscan2
- PADI3 | c.1731G>A p.R577= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV64934356; called by muse, mutect2, varscan2
- PAK3 | c.1176C>T p.F392= (on ENST00000262836 / NM_001324328.2; = p.F377= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 48/76 reads (63%) | catalogued as COSV53276029; called by muse, mutect2, varscan2
- PCDHB15 | c.567G>A p.R189= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1039707853, COSV51049411; called by muse, mutect2, varscan2
- PCLO | c.4656G>A p.E1552= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV61645408; called by muse, mutect2, varscan2
- PCLO | c.2208A>G p.K736= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV61645419; called by muse, mutect2, varscan2
- PDCD11 | c.5274G>A p.K1758= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV53296509; called by muse, mutect2, varscan2
- PDE6A | c.1038C>T p.L346= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs1352860187, COSV54928894; called by muse, mutect2, varscan2
- PER1 | c.678C>T p.F226= | Silent (SNP) | VAF 57/125 reads (46%) | catalogued as rs745411228, COSV57920483; called by muse, mutect2, varscan2
- PFKFB3 | c.372C>T p.F124= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as rs748952044, COSV57987721; called by muse, mutect2, varscan2
- PLA2R1 | c.2887C>T p.L963= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV51781511; called by muse, mutect2, varscan2
- PRAMEF14 | c.1302G>A p.R434= | Silent (SNP) | VAF 51/180 reads (28%) | catalogued as COSV100577272; called by muse, mutect2, varscan2
- PROKR1 | c.723C>T p.F241= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as rs146411193; called by muse, mutect2, varscan2
- PRSS37 | c.630C>T p.F210= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV63339295, COSV63339630; called by muse, mutect2, varscan2
- PTGFR | c.870C>T p.L290= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV66115650; called by muse, mutect2, varscan2
- PTPRD | c.4815C>T p.I1605= | Silent (SNP) | VAF 85/199 reads (43%) | catalogued as COSV61958848; called by muse, mutect2, varscan2
- PWWP3B | c.1227G>A p.V409= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV61800417; called by muse, mutect2, varscan2
- PXDNL | c.3012C>T p.I1004= | Silent (SNP) | VAF 13/14 reads (93%) | catalogued as rs1370331286, COSV62479760; called by muse, mutect2, varscan2
- RAI1 | c.3930C>T p.F1310= | Silent (SNP) | VAF 59/127 reads (46%) | catalogued as COSV99883573; called by muse, mutect2, varscan2
- RAPGEF1 | c.2415C>T p.I805= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV64700403; called by muse, mutect2, varscan2
- RASIP1 | c.2463G>A p.L821= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs374487489; called by muse, mutect2, varscan2
- RASSF2 | c.684G>A p.T228= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as rs371941310; called by muse, mutect2, varscan2
- RDH16 | c.105G>A p.T35= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as rs763600858, COSV62458374; called by muse, mutect2, varscan2
- RFXANK | c.126C>T p.L42= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as COSV50765847; called by muse, mutect2, varscan2
- RGS6 | c.816C>T p.I272= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs777346546, COSV59583853; called by muse, mutect2, varscan2
- RHOT2 | c.1722C>G p.A574= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV54808182, COSV54809169; called by muse, mutect2, varscan2
- RMDN3 | c.1275C>T p.S425= | Silent (SNP) | VAF 47/156 reads (30%) | catalogued as COSV99539884; called by muse, mutect2, varscan2
- SALL1 | c.3276C>T p.F1092= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs768302293, COSV51754182; called by muse, mutect2, varscan2
- SCG2 | c.792G>A p.E264= | Silent (SNP) | VAF 104/232 reads (45%) | catalogued as rs770954298, COSV59540681; called by muse, mutect2, varscan2
- SEPSECS | c.1350C>T p.F450= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV57206301; called by muse, varscan2
- SEPTIN12 | c.747G>A p.V249= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs774447541, COSV51617780; called by muse, mutect2, varscan2
- SERPINA11 | c.675G>A p.Q225= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as COSV58241388, COSV58242411; called by muse, mutect2, varscan2
- SIGLEC8 | c.618C>T p.S206= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV58474469; called by muse, mutect2, varscan2
- SLC39A11 | c.912C>T p.Y304= (on ENST00000542342 / NM_001159770.2; = p.Y297= on NM_139177.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs146713017; called by muse, mutect2, varscan2
- SLC8A1 | c.2451C>T p.F817= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs770080096, COSV60486497; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC9A4 | c.846C>T p.I282= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs759238987, COSV54834011, COSV99763034; called by muse, mutect2, varscan2
- SLC9A6 | c.885C>T p.F295= | Silent (SNP) | VAF 42/61 reads (69%) | catalogued as COSV65788347; called by muse, mutect2, varscan2
- SMIM21 | c.237A>G p.K79= | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as COSV66895156; called by muse, mutect2, varscan2
- SORCS2 | c.1716G>A p.V572= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV61174300; called by muse, mutect2, varscan2
- SPATA31E1 | c.2463C>T p.S821= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs991920114, COSV100350070; called by muse, mutect2, varscan2
- SPDYA | c.783G>A p.Q261= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100477868; called by muse, mutect2, varscan2
- SPHK2 | c.948G>A p.L316= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV55338838; called by muse, mutect2, varscan2
- SPTLC3 | c.477C>T p.I159= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs751680123, COSV65466647; called by muse, mutect2, varscan2
- SRRM3 | c.240G>A p.S80= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs782054672, COSV100418619, COSV58388935; called by muse, mutect2, varscan2
- SSTR2 | c.207C>A p.L69= | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as COSV59535396; called by muse, mutect2, varscan2
- SUCO | c.567C>T p.V189= | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as COSV55267272; called by muse, mutect2, varscan2
- TAS1R2 | c.1965C>T p.I655= | Silent (SNP) | VAF 57/163 reads (35%) | catalogued as rs751000756, COSV64744620; called by muse, mutect2, varscan2
- TENM3 | c.1335C>T p.F445= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs747292851, COSV69299297; called by muse, varscan2
- TICAM1 | c.1989C>T p.F663= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV50233931, COSV50241765; called by muse, varscan2
- TMC3 | c.645G>A p.R215= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV63923617; called by muse, mutect2, varscan2
- TMEM132D | c.723G>A p.R241= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV70610746; called by muse, mutect2, varscan2
- TMEM200A | c.177C>T p.S59= | Silent (SNP) | VAF 65/148 reads (44%) | catalogued as COSV51655174; called by muse, mutect2, varscan2
- TMEM200A | c.414C>T p.F138= | Silent (SNP) | VAF 41/81 reads (51%) | catalogued as COSV51655186; called by muse, mutect2, varscan2
- TMEM35A | c.165G>A p.K55= | Silent (SNP) | VAF 51/63 reads (81%) | catalogued as COSV54503904; called by muse, mutect2, varscan2
- TMEM59L | c.831C>T p.S277= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs768319181, COSV53242034; called by muse, mutect2, varscan2
- TNFAIP3 | c.591T>C p.F197= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as COSV52799953; called by muse, mutect2, varscan2
- TPM2 | c.261C>T p.S87= | Silent (SNP) | VAF 45/73 reads (62%) | catalogued as rs267602228, COSV61406622; called by muse, mutect2, varscan2
- TRPM2 | c.3582C>T p.I1194= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as rs372711130, COSV55972703; called by muse, varscan2
- TRPS1 | c.270C>T p.S90= (on ENST00000220888 / NM_001330599.2; = p.S103= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 101/129 reads (78%) | catalogued as COSV55248695; called by muse, mutect2, varscan2
- TTC7A | c.711C>T p.T237= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV55412585; called by muse, mutect2, varscan2
- UNC13A | c.3405G>A p.K1135= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV99407451; called by muse, mutect2, varscan2
- URB2 | c.1212C>T p.P404= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs771513516, COSV51000478; called by muse, mutect2, varscan2
- WHRN | c.2040C>T p.F680= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as rs1299317856, COSV54332175; called by muse, mutect2, varscan2
- XRCC6 | c.642C>T p.S214= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV63753167; called by muse, mutect2, varscan2
- ZNF280A | c.237C>T p.F79= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs375668247; called by muse, varscan2
- ZNF526 | c.1023C>T p.F341= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV55899841; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918840 C>T | 5'Flank (SNP) | VAF 18/30 reads (60%) | catalogued as rs1403195329, COSV62703986; called by muse, mutect2, varscan2
- BTN2A3P | n.884G>A | RNA (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- CBX2 | c.288+162C>A | Intron (SNP) | VAF 40/153 reads (26%) | catalogued as COSV99490778; called by muse, mutect2, varscan2
- DCHS2 | n.7604C>T | RNA (SNP) | VAF 9/36 reads (25%) | catalogued as rs748475572, COSV61769754; called by muse, mutect2, varscan2
- ELAVL4 | c.9+763G>A | Intron (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100836615; called by muse, mutect2, varscan2
- FOLH1B | n.1025G>A | RNA (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.85G>A | RNA (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- MIR655 | n.26G>A | RNA (SNP) | VAF 26/89 reads (29%) | catalogued as rs766575622; called by muse, mutect2, varscan2
- MIR924 | n.48T>A | RNA (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- OR3A4P | n.753T>G | RNA (SNP) | VAF 33/109 reads (30%) | called by muse, mutect2, varscan2
- PRSS3 | c.-42C>T | 5'UTR (SNP) | VAF 39/73 reads (53%) | catalogued as rs142082180; called by muse, varscan2
- RAB3GAP2 | c.811+1602C>T | Intron (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99424505; called by muse, mutect2, varscan2
- SWI5 | c.-96C>T | 5'UTR (SNP) | VAF 11/31 reads (35%) | catalogued as COSV60791472; called by muse, mutect2, varscan2
- TTN | c.10361-5115G>A | Intron (SNP) | VAF 50/111 reads (45%) | catalogued as rs867025684, COSV100599732; called by muse, mutect2, varscan2
- TTN | c.10360+4243C>T | Intron (SNP) | VAF 27/98 reads (28%) | catalogued as COSV100599733; called by muse, mutect2, varscan2
- USH1C | c.1284+7705C>T | Intron (SNP) | VAF 23/34 reads (68%) | catalogued as rs1436939495, COSV99139479, COSV99139971; called by muse, mutect2, varscan2
- ZNF99 | c.*630A>C | 3'UTR (SNP) | VAF 16/48 reads (33%) | catalogued as rs760002754, COSV101233742; called by muse, varscan2
